CCDI case PBCHUX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cfdbe75b-1ed1-48f1-a225-a11a23ca402a

Demographics
Sex at birth: female; Race: american indian or alaska native.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.0 years (378 days).

Biospecimens (3 samples)
- Sample 0DSEYW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEZ9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSF02: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
